Somatic mutation profile of tumor specimen C3L-01157-03 (aliquot CPT0199770006) from CPTAC case C3L-01157, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 66.7 years (24,372 days).
Specimen C3L-01157-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 20143d7e-7ec6-4fca-b894-8ff25eb11e59.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01157-31 (Blood Derived Normal), aliquot CPT0200400002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e42455d-ec48-4805-91f9-43d455f4f902

The open-access MAF lists 64 somatic variants for this specimen: 40 protein-altering or splice-affecting, 16 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 16, Intron 6, Frame Shift Del 1, 3'UTR 1, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRV1 | c.2746G>A p.V916I | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs771551901; called by muse, mutect2, varscan2
- CCDC85A | c.1133G>A p.S378N | Missense Mutation (SNP) | VAF 55/224 reads (25%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.023); catalogued as rs533959630; called by muse, mutect2, varscan2
- CDH7 | c.921G>T p.L307F | Missense Mutation (SNP) | VAF 37/141 reads (26%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.756); catalogued as COSV59889474; called by muse, mutect2, varscan2
- CDRT1 | c.967G>A p.G323S | Missense Mutation (SNP) | VAF 64/260 reads (25%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs765289581; called by muse, mutect2, varscan2
- CLCNKB | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 96/258 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as rs140923370; called by muse, mutect2, varscan2
- CORIN | c.2425C>T p.R809C | Missense Mutation (SNP) | VAF 76/291 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777099502, COSV56692609; called by muse, mutect2, varscan2
- FER1L6 | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 85/264 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as rs1346494073, COSV67551985; called by muse, varscan2
- HMCES | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs371706577; called by muse, mutect2, varscan2
- KCNE3 | c.43C>T p.H15Y | Missense Mutation (SNP) | VAF 51/171 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.191); catalogued as rs776896849; called by muse, mutect2, varscan2
- KLHL34 | c.1049C>T p.T350M | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs781010000; called by muse, varscan2
- LRRK1 | c.4907T>C p.I1636T | Missense Mutation (SNP) | VAF 83/280 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as rs932536919; called by muse, mutect2, varscan2
- NMRK1 | c.335G>A p.W112* | Nonsense Mutation (SNP) | VAF 23/85 reads (27%) | catalogued as COSV100737979; called by muse, mutect2, varscan2
- NOC2L | c.2095G>A p.D699N | Missense Mutation (SNP) | VAF 57/209 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.114); catalogued as rs371201923; called by muse, varscan2
- NPY2R | c.106C>A p.P36T | Missense Mutation (SNP) | VAF 58/168 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs755752109; called by mutect2, varscan2
- PRKAR2B | c.853C>T p.R285C | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1204029640, COSV99707854; called by muse, mutect2, varscan2
- PYGL | c.231C>G p.D77E | Missense Mutation (SNP) | VAF 97/187 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as CD154451; called by muse, mutect2, varscan2
- SEC16A | c.5801C>T p.A1934V | Missense Mutation (SNP) | VAF 89/286 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as rs748018933; called by muse, mutect2, varscan2
- SPTB | c.4643C>T p.A1548V | Missense Mutation (SNP) | VAF 82/172 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.108); catalogued as rs377634587; called by muse, mutect2, varscan2
- TREX2 | c.742G>T p.A248S (on ENST00000334497; = p.A205S on NM_080701.3) | Missense Mutation (SNP) | VAF 21/785 reads (3%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.997); catalogued as COSV57848076; called by muse, mutect2
- TRPV5 | c.1327C>T p.R443W | Missense Mutation (SNP) | VAF 67/269 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.245); catalogued as rs775179978, COSV54688182; called by muse, mutect2, varscan2
- TTN | c.90770C>A p.S30257Y (on ENST00000591111; = p.S22833Y on NM_003319.4) | Missense Mutation (SNP) | VAF 16/42 reads (38%) | PolyPhen probably damaging (0.98); catalogued as COSV60190168; called by muse, mutect2
- ZFP30 | c.1457G>A p.R486K | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.054); catalogued as rs777324427, COSV63622379, COSV63622436; called by muse, mutect2, varscan2
- CDC42BPA | c.299A>G p.D100G | Missense Mutation (SNP) | VAF 25/158 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- CFAP20DC | c.1347C>A p.N449K (on ENST00000482387 / NM_001351530.2; = p.N324K on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 105/325 reads (32%) | SIFT tolerated (0.78); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CNKSR2 | c.953T>A p.L318Q | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- CSPG4 | c.6737T>A p.L2246H | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FLG2 | c.91G>T p.G31C | Missense Mutation (SNP) | VAF 56/191 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- HELB | c.914G>T p.C305F | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ITGAE | c.2140A>G p.T714A | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LAG3 | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 56/157 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- MARK1 | c.1078del p.E360Kfs*9 | Frame Shift Del (DEL) | VAF 19/52 reads (37%) | called by mutect2, pindel, varscan2
- MRTFA | c.2276T>A p.I759N | Missense Mutation (SNP) | VAF 77/270 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- MYO1D | c.58G>A p.V20I | Missense Mutation (SNP) | VAF 104/310 reads (34%) | SIFT tolerated (0.66); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- OR8B2 | c.914T>A p.I305N | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- PCSK6 | c.488C>A p.P163H | Missense Mutation (SNP) | VAF 103/358 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- PGRMC1 | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 32/400 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.266); called by muse, mutect2
- PRKG2 | c.179A>T p.K60M | Missense Mutation (SNP) | VAF 94/281 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- SIDT1 | c.1811C>T p.A604V | Missense Mutation (SNP) | VAF 57/199 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- SOX5 | c.2062T>C p.S688P | Missense Mutation (SNP) | VAF 90/267 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- USP51 | c.949A>G p.T317A | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2
- AATK | c.1749C>T p.P583= (on ENST00000326724 / NM_001080395.3; = p.P480= on NM_004920.2) | Silent (SNP) | VAF 32/109 reads (29%) | catalogued as rs772110351; called by muse, mutect2, varscan2
- ADGRD2 | c.1158G>A p.A386= | Silent (SNP) | VAF 51/185 reads (28%) | catalogued as rs747326349; called by muse, mutect2, varscan2
- BAZ1A | c.744G>A p.T248= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as rs1309627549, COSV62411892; called by muse, mutect2, varscan2
- CMYA5 | c.429A>G p.P143= | Silent (SNP) | VAF 14/68 reads (21%) | called by muse, mutect2, varscan2
- DOCK7 | c.4431A>G p.T1477= (on ENST00000635253 / NM_001367561.1; = p.T1446= on NM_033407.3) | Silent (SNP) | VAF 45/141 reads (32%) | called by muse, mutect2, varscan2
- GNAS | c.1239C>T p.S413= | Silent (SNP) | VAF 210/675 reads (31%) | catalogued as rs200870807; called by muse, mutect2, varscan2
- GPR87 | c.807C>T p.H269= | Silent (SNP) | VAF 53/210 reads (25%) | catalogued as rs779582675; called by muse, mutect2, varscan2
- INTS1 | c.459C>T p.R153= | Silent (SNP) | VAF 86/378 reads (23%) | catalogued as rs199826626, COSV67176625; called by muse, mutect2, varscan2
- ITIH6 | c.2487T>C p.P829= | Silent (SNP) | VAF 54/166 reads (33%) | called by muse, mutect2, varscan2
- OR1N1 | c.216G>A p.T72= | Silent (SNP) | VAF 65/186 reads (35%) | catalogued as rs1244720592; called by muse, mutect2, varscan2
- OR2T12 | c.516C>T p.I172= | Silent (SNP) | VAF 130/607 reads (21%) | catalogued as rs1186607809, COSV58777432, COSV58778756; called by muse, mutect2, varscan2
- PPFIA4 | c.57C>T p.G19= | Silent (SNP) | VAF 170/353 reads (48%) | catalogued as rs546001209; called by muse, mutect2, varscan2
- SLC12A3 | c.378C>T p.S126= | Silent (SNP) | VAF 129/470 reads (27%) | catalogued as rs1567424954, COSV52637270; called by muse, mutect2, varscan2
- SLC34A2 | c.1650C>T p.A550= | Silent (SNP) | VAF 128/427 reads (30%) | catalogued as rs1560243361, COSV65942819; called by muse, mutect2, varscan2
- TRIP4 | c.961C>A p.R321= | Silent (SNP) | VAF 105/380 reads (28%) | catalogued as COSV56031350; called by muse, mutect2, varscan2
- TRPM4 | c.2283C>T p.G761= | Silent (SNP) | VAF 100/302 reads (33%) | called by muse, mutect2, varscan2
- ACAA1 | c.323+71C>T | Intron (SNP) | VAF 39/147 reads (27%) | called by muse, mutect2, varscan2
- IGSF22 | c.2095+1471G>A | Intron (SNP) | VAF 33/98 reads (34%) | catalogued as rs779954161, COSV60036507; called by muse, mutect2, varscan2
- MYO15B | c.8416-115C>T | Intron (SNP) | VAF 86/274 reads (31%) | catalogued as rs562503830; called by muse, mutect2, varscan2
- PINK1 | c.675+39C>A | Intron (SNP) | VAF 36/125 reads (29%) | called by muse, mutect2, varscan2
- SGO2 | c.*2G>A | 3'UTR (SNP) | VAF 13/54 reads (24%) | catalogued as rs1300190644; called by muse, mutect2, varscan2
- SPG7 | c.1304-44C>T | Intron (SNP) | VAF 122/397 reads (31%) | called by muse, mutect2, varscan2
- STXBP2 | c.247-395G>A | Intron (SNP) | VAF 132/429 reads (31%) | called by muse, mutect2, varscan2
- TEX101 | c.-21G>A | 5'UTR (SNP) | VAF 30/145 reads (21%) | catalogued as rs908676972, COSV99494681; called by muse, mutect2, varscan2
